Somatic mutation profile of tumor specimen MP2PRT-PARWXW-TMP1-A (aliquot MP2PRT-PARWXW-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARWXW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,011 days).
Specimen MP2PRT-PARWXW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a534d7ce-d804-4c7b-ac9c-aeddd659185c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWXW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWXW-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b29dedc8-fa19-4b9e-b757-e51730ff4b9a

The open-access MAF lists 112 somatic variants for this specimen: 78 protein-altering or splice-affecting, 28 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 28, Nonsense Mutation 6, Intron 2, 3'UTR 2, 5'Flank 1, 3'Flank 1, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3604G>A p.G1202R | Missense Mutation (SNP) | VAF 241/593 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519783, COSV66555808; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.6187C>T p.R2063W | Missense Mutation (SNP) | VAF 239/616 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs121912849, CM970380, CM970381, COSV60392347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 92/276 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AIPL1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 327/1152 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV100005975; called by muse, mutect2, varscan2
- ALK | c.3605G>A p.G1202E | Missense Mutation (SNP) | VAF 236/585 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1244270149, CD1210462, COSV66586142; called by muse, mutect2, varscan2
- ARHGAP22 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 59/1442 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs761801837; called by muse, mutect2
- CA8 | c.417G>A p.E139= | Splice Region (SNP) | VAF 81/195 reads (42%) | catalogued as COSV58771819; called by muse, mutect2
- CLASRP | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 507/1222 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as rs543464549; called by muse, mutect2, varscan2
- DBX2 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 245/1085 reads (23%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.517); catalogued as rs1432461840; called by muse, mutect2, varscan2
- DENND2A | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 142/346 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745399243, COSV52059516; called by muse, mutect2, varscan2
- EPHA6 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67559476; called by muse, mutect2, varscan2
- FANK1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 158/321 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748738165, COSV64156251; called by muse, mutect2, varscan2
- FBN2 | c.8498G>A p.R2833H | Missense Mutation (SNP) | VAF 273/690 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as rs753753954, COSV52548002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GREB1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 270/658 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52195307; called by muse, mutect2, varscan2
- IQUB | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 72/182 reads (40%) | catalogued as COSV61240313, COSV61242279; called by muse, mutect2, varscan2
- KIF25 | c.1043C>T p.A348V (on ENST00000354419 / NM_030615.2; = p.A296V on NM_005355.3) | Missense Mutation (SNP) | VAF 356/811 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as rs202094020; called by muse, mutect2, varscan2
- KIF26B | c.4405C>T p.P1469S | Missense Mutation (SNP) | VAF 434/1019 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1490215225; called by muse, mutect2, varscan2
- LIFR | c.1551G>T p.W517C | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54701463; called by muse, mutect2, varscan2
- MIDN | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 625/1422 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs770403819; called by muse, mutect2, varscan2
- MYCBPAP | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 324/1135 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1262654415, COSV100088185; called by muse, mutect2, varscan2
- MYO15A | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 317/1054 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1165128799, COSV52757008; called by muse, mutect2, varscan2
- NAALAD2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1041517727, COSV58963008; called by muse, mutect2, varscan2
- NCOR1 | c.5017C>T p.P1673S | Missense Mutation (SNP) | VAF 94/372 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV52001939; called by muse, mutect2, varscan2
- NSFL1C | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 175/492 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs201890755, COSV53792894, COSV99401474; called by muse, mutect2, varscan2
- OR10G4 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100305046; called by muse, mutect2, varscan2
- OR5AR1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 208/488 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs760402764, COSV57254278; called by muse, mutect2, varscan2
- OTOF | c.3952G>A p.E1318K (on ENST00000272371 / NM_194248.3; = p.E551K on NM_004802.4) | Missense Mutation (SNP) | VAF 240/612 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV55503518; called by muse, varscan2
- PLB1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as rs765739799, COSV59820159, COSV59836566; called by muse, mutect2, varscan2
- PLD5 | c.880G>A p.E294K (on ENST00000442594; = p.E232K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV59165350; called by muse, mutect2, varscan2
- PLEKHG4B | c.1576G>A p.E526K (on ENST00000283426; = p.E882K on NM_052909.5) | Missense Mutation (SNP) | VAF 202/435 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs755737878; called by muse, mutect2, varscan2
- POTEE | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 322/850 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1390475550, COSV58232713; called by muse, mutect2, varscan2
- RYR1 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 33/865 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614749; called by muse, mutect2
- RYR1 | c.3568G>A p.V1190I | Missense Mutation (SNP) | VAF 149/394 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.771); catalogued as rs749283427, COSV62101459; called by muse, mutect2, varscan2
- SAMD9 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs368696956; called by muse, mutect2, varscan2
- TBX21 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 364/1215 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1297045032, COSV51597912; called by muse, mutect2, varscan2
- VLDLR | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs755556422, COSV66074522; called by muse, mutect2, varscan2
- YME1L1 | c.397C>T p.Q133* (on ENST00000326799 / NM_139312.3; = p.Q76* on NM_014263.4) | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as COSV58761308; called by muse, mutect2, varscan2
- ZNF469 | c.9380C>T p.S3127L (on ENST00000437464; = p.S3155L on NM_001367624.2) | Missense Mutation (SNP) | VAF 473/1126 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953786373; called by muse, mutect2, varscan2
- ADAMTS5 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 460/1917 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- AHNAK2 | c.5354C>T p.S1785F | Missense Mutation (SNP) | VAF 225/582 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, varscan2
- ALMS1 | c.6403C>A p.P2135T | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ANK2 | c.9728C>T p.S3243F | Missense Mutation (SNP) | VAF 268/516 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ANKRD33B | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 466/1172 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BCL11B | c.1922G>A p.G641D (on ENST00000357195 / NM_001282237.2; = p.G570D on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BEND6 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRT2 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 26/860 reads (3%) | called by muse, mutect2
- DSCAM | c.786C>A p.N262K | Missense Mutation (SNP) | VAF 289/1383 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ENPP1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 137/356 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.4841G>A p.W1614* | Nonsense Mutation (SNP) | VAF 235/556 reads (42%) | called by muse, mutect2, varscan2
- FER1L5 | c.2468G>A p.G823E (on ENST00000623019; = p.G828E on NM_001293083.2) | Missense Mutation (SNP) | VAF 204/518 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- FER1L6 | c.3204G>A p.W1068* | Nonsense Mutation (SNP) | VAF 251/654 reads (38%) | called by muse, mutect2, varscan2
- FLG | c.7216G>A p.G2406R | Missense Mutation (SNP) | VAF 191/614 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- GBA2 | c.72_73dup p.D25Gfs*45 | Frame Shift Ins (INS) | VAF 238/635 reads (37%) | called by mutect2, pindel, varscan2
- GJD4 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 495/955 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HFM1 | c.347A>T p.H116L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IARS1 | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005626 TCCTCACACAGTGGTACAG>CTCCCCTTCCTC | Missense Mutation (DEL) | VAF 74/104 reads (71%) | called by pindel, varscan2*
- IL1RAP | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 98/539 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- KCTD4 | c.757_758del p.D253Cfs*52 | Frame Shift Del (DEL) | VAF 46/143 reads (32%) | called by pindel*, varscan2
- LINGO2 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 270/650 reads (42%) | called by muse, mutect2, varscan2
- LYST | c.2215C>T p.L739F | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- MBD5 | c.3781G>A p.E1261K | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MED13 | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MIA | c.261C>G p.S87R | Missense Mutation (SNP) | VAF 156/352 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYRIP | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 228/599 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- OTOL1 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 227/507 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRPF40B | c.2609A>C p.H870P (on ENST00000380281; = p.H857P on NM_012272.3) | Missense Mutation (SNP) | VAF 159/443 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRM | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RYR2 | c.10540C>T p.H3514Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCAF1 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 405/963 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SPOCK1 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 222/544 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TECTA | c.1979C>T p.T660I | Missense Mutation (SNP) | VAF 363/849 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TLR3 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 112/378 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TMEM212 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TRMT2B | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR35 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZCCHC3 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 39/1244 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- ZNF804A | c.3592C>T p.P1198S | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS10 | c.2547G>A p.A849= | Silent (SNP) | VAF 23/806 reads (3%) | called by muse, mutect2
- AOPEP | c.1374C>T p.I458= | Silent (SNP) | VAF 110/338 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.912G>A p.A304= | Silent (SNP) | VAF 241/895 reads (27%) | called by muse, mutect2, varscan2
- C1orf87 | c.153G>A p.Q51= | Silent (SNP) | VAF 85/187 reads (45%) | called by muse, mutect2, varscan2
- CLASRP | c.1581C>T p.S527= | Silent (SNP) | VAF 512/1230 reads (42%) | catalogued as rs773445420; called by muse, mutect2, varscan2
- CNNM1 | c.2556C>T p.S852= | Silent (SNP) | VAF 27/356 reads (8%) | catalogued as rs764844791, COSV63203027; called by muse, mutect2
- CPT1B | c.1791C>T p.F597= | Silent (SNP) | VAF 253/622 reads (41%) | called by muse, varscan2
- FAM3A | c.252C>T p.P84= | Silent (SNP) | VAF 301/683 reads (44%) | called by muse, mutect2, varscan2
- FMN1 | c.3625C>T p.L1209= (on ENST00000616417 / NM_001277313.2; = p.L986= on NM_001103184.4) | Silent (SNP) | VAF 103/240 reads (43%) | called by muse, mutect2, varscan2
- FUT5 | c.561G>A p.P187= | Silent (SNP) | VAF 38/982 reads (4%) | catalogued as rs759015583, COSV99398685; called by muse, mutect2
- GPR39 | c.1209G>A p.R403= | Silent (SNP) | VAF 339/752 reads (45%) | catalogued as COSV61415902; called by muse, mutect2, varscan2
- LINGO2 | c.1470G>A p.G490= | Silent (SNP) | VAF 225/531 reads (42%) | catalogued as COSV58057279; called by muse, mutect2, varscan2
- MAP1A | c.5574C>T p.S1858= | Silent (SNP) | VAF 29/777 reads (4%) | catalogued as COSV55811166; called by muse, mutect2
- MUC12 | c.8577C>T p.T2859= (on ENST00000379442; = p.T2716= on NM_001164462.1) | Silent (SNP) | VAF 283/7262 reads (4%) | catalogued as rs557981226; called by muse, mutect2
- MYCBPAP | c.1998G>A p.R666= | Silent (SNP) | VAF 324/1142 reads (28%) | catalogued as COSV100088182; called by muse, mutect2, varscan2
- MYRIP | c.840C>T p.S280= | Silent (SNP) | VAF 233/607 reads (38%) | called by muse, mutect2, varscan2
- NYX | c.750C>T p.F250= | Silent (SNP) | VAF 476/1078 reads (44%) | catalogued as COSV99070450; called by muse, mutect2, varscan2
- OR10A4 | c.702G>A p.G234= | Silent (SNP) | VAF 158/404 reads (39%) | catalogued as COSV65842412; called by muse, mutect2, varscan2
- OR2T27 | c.108G>A p.L36= | Silent (SNP) | VAF 196/879 reads (22%) | catalogued as COSV100788249; called by muse, mutect2, varscan2
- PCSK9 | c.927C>T p.V309= | Silent (SNP) | VAF 417/956 reads (44%) | catalogued as rs1349702593; called by muse, mutect2, varscan2
- PCSK9 | c.1977G>A p.R659= | Silent (SNP) | VAF 388/864 reads (45%) | called by muse, mutect2, varscan2
- PRLR | c.675G>A p.Q225= | Silent (SNP) | VAF 136/315 reads (43%) | called by muse, mutect2, varscan2
- QRFPR | c.744G>A p.G248= | Silent (SNP) | VAF 120/256 reads (47%) | catalogued as rs1251671039; called by muse, mutect2, varscan2
- RAP2A | c.25C>T p.L9= | Silent (SNP) | VAF 218/420 reads (52%) | catalogued as rs376462354; called by muse, varscan2
- SLC22A6 | c.87C>T p.L29= | Silent (SNP) | VAF 322/794 reads (41%) | called by muse, mutect2, varscan2
- VLDLR | c.1035G>A p.R345= | Silent (SNP) | VAF 65/228 reads (29%) | called by muse, mutect2, varscan2
- ZNF268 | c.825C>T p.P275= | Silent (SNP) | VAF 9/242 reads (4%) | called by muse, mutect2
- ZNF318 | c.2712C>T p.A904= | Silent (SNP) | VAF 93/236 reads (39%) | called by muse, mutect2, varscan2
- EFEMP2 | c.*235G>A | 3'UTR (SNP) | VAF 59/754 reads (8%) | called by muse, mutect2
- EFEMP2 | c.*234G>A | 3'UTR (SNP) | VAF 58/750 reads (8%) | catalogued as rs1281906215; called by muse, mutect2
- KCNQ1 | c.1394-28364C>T | Intron (SNP) | VAF 45/109 reads (41%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46833651 G>A | 3'Flank (SNP) | VAF 362/827 reads (44%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248441287 G>A | 5'Flank (SNP) | VAF 72/273 reads (26%) | catalogued as rs751255971; called by muse, mutect2, varscan2
- RMDN2 | c.453-21981G>A | Intron (SNP) | VAF 55/120 reads (46%) | catalogued as rs148301050; called by muse, mutect2, varscan2
